Somatic mutation profile of tumor specimen ALCH-B2T2-TTP1-B (aliquot ALCH-B2T2-TTP1-B-1-0-D-A83F-36) from ALCHEMIST case ALCH-B2T2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.9 years (21,156 days).
Specimen ALCH-B2T2-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b07b0558-dabd-4125-adbb-f33eb0b12872.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2T2-NB1-A (Blood Derived Normal), aliquot ALCH-B2T2-NB1-A-1-0-D-A83F-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e610b086-d8b4-4914-a659-bbb729cd80c0

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 2, 3'Flank 1, 3'UTR 1, In Frame Del 1, Splice Site 1, Splice Region 1, Intron 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 58/402 reads (14%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- AHSG | c.935C>A p.A312E | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as COSV56609041; called by muse, mutect2, varscan2
- C6orf118 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as rs1054831688, COSV57816003; called by muse, mutect2, varscan2
- SYT10 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0.027); catalogued as COSV57341265; called by muse, mutect2
- CHMP4B | c.253A>G p.T85A | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.401); called by muse, mutect2
- GPR137 | c.784-7_790del p.X262_splice | Splice Site (DEL) | VAF 15/99 reads (15%) | called by mutect2, pindel, varscan2
- LRP5 | c.3636C>T p.F1212= | Splice Region (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- MIA2 | c.90G>A p.M30I | Missense Mutation (SNP) | VAF 80/328 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- MICA | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MRPL18 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 60/366 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OTOG | c.7718C>A p.S2573Y | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PCDHA1 | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 22/576 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); called by muse, mutect2
- PDE1C | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 19/384 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); called by muse, mutect2
- PSG8 | c.228C>A p.Y76* | Nonsense Mutation (SNP) | VAF 13/307 reads (4%) | called by muse, mutect2
- RXFP1 | c.956A>G p.K319R | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2
- RYR3 | c.9619C>T p.P3207S (on ENST00000389232; = p.P3208S on NM_001036.6) | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.033); called by muse, mutect2
- SAXO2 | c.801G>T p.R267S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SLC16A2 | c.343T>C p.F115L | Missense Mutation (SNP) | VAF 35/326 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- SSX3 | c.234C>A p.D78E | Missense Mutation (SNP) | VAF 18/417 reads (4%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.986); called by muse, mutect2
- PCDH17 | c.219C>T p.H73= | Silent (SNP) | VAF 43/308 reads (14%) | called by muse, mutect2, varscan2
- STAG1 | c.378G>A p.Q126= | Silent (SNP) | VAF 37/267 reads (14%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.*860T>C | 3'UTR (SNP) | VAF 12/90 reads (13%) | called by muse, mutect2, varscan2
- AK2 | chr1:33008590 G>T | 3'Flank (SNP) | VAF 14/98 reads (14%) | called by muse, mutect2, varscan2
- CCDC120 | c.-49C>A | 5'UTR (SNP) | VAF 77/342 reads (23%) | called by muse, mutect2, varscan2
- TLN2 | c.-36-7067G>C | Intron (SNP) | VAF 23/235 reads (10%) | called by muse, mutect2, varscan2
